Somatic mutation profile of tumor specimen TCGA-G2-A2EJ-01A (aliquot TCGA-G2-A2EJ-01A-11D-A17V-08) from TCGA case TCGA-G2-A2EJ, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage II; Tumor grade: High Grade; Age at diagnosis: 56.5 years (20,649 days).
Specimen TCGA-G2-A2EJ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3ec91fdd-da8b-49cd-925c-13cf3487861b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-G2-A2EJ-10A (Blood Derived Normal), aliquot TCGA-G2-A2EJ-10A-01D-A17V-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7ff3d59e-14e5-45af-b867-4e5e3e01f357

The open-access MAF lists 347 somatic variants for this specimen: 265 protein-altering or splice-affecting, 74 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 226, Silent 74, Nonsense Mutation 22, Frame Shift Del 6, Splice Site 6, Intron 5, Frame Shift Ins 2, RNA 2, Splice Region 2, Translation Start Site 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.172C>T p.R58* | Nonsense Mutation (SNP) | VAF 4/13 reads (31%) | hotspot (GDC flag); catalogued as rs121913387, CM940227, COSV58682666, COSV58721549, COSV99053472; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- HRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 9/43 reads (21%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.339); catalogued as rs104894230, CM053284, CM081305, CM123157, COSV54236734, COSV54236774, COSV54238174; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.733G>A p.G245S | Missense Mutation (SNP) | VAF 29/57 reads (51%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs28934575, CM010463, CM900210, CM920674, COSV52661744, COSV52661877, COSV52713951, COSV52839866; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA12 | c.2341T>C p.C781R (on ENST00000272895 / NM_173076.3; = p.C463R on NM_015657.3) | Missense Mutation (SNP) | VAF 15/27 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55969456; called by muse, mutect2, varscan2
- ABCA9 | c.3661C>T p.R1221* | Nonsense Mutation (SNP) | VAF 6/28 reads (21%) | catalogued as rs377378801; called by mutect2, varscan2
- ABCG4 | c.1134C>G p.F378L | Missense Mutation (SNP) | VAF 101/305 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.036); catalogued as COSV56645012; called by muse, mutect2, varscan2
- ACTG1 | c.169G>A p.E57K | Missense Mutation (SNP) | VAF 53/81 reads (65%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as COSV59511428; called by muse, mutect2, varscan2
- ACTN1 | c.337G>A p.E113K | Missense Mutation (SNP) | VAF 30/141 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs752533755, COSV51995348; called by muse, mutect2, varscan2
- ADAM17 | c.1582G>A p.E528K | Missense Mutation (SNP) | VAF 62/196 reads (32%) | SIFT tolerated (0.31); PolyPhen benign (0.06); catalogued as COSV60400904; called by muse, mutect2, varscan2
- ADAMTS16 | c.502-1G>T p.X168_splice | Splice Site (SNP) | VAF 20/97 reads (21%) | catalogued as COSV57000595; called by muse, mutect2, varscan2
- ADAMTS20 | c.578C>T p.S193F | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.012); catalogued as COSV67130605, COSV67134713; called by muse, mutect2, varscan2
- ADGRV1 | c.11242G>C p.E3748Q | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as COSV67991675; called by muse, mutect2, varscan2
- AFAP1L1 | c.1869G>T p.L623F | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.82); catalogued as COSV57046748; called by mutect2, varscan2
- AKNA | c.2209G>C p.E737Q | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.69); catalogued as COSV56314122; called by muse, mutect2, varscan2
- AMER1 | c.592G>A p.E198K | Missense Mutation (SNP) | VAF 18/89 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.011); catalogued as rs774927630, COSV57660170, COSV57664825; called by muse, mutect2, varscan2
- ANK3 | c.11026G>C p.E3676Q | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.229); catalogued as COSV55072688; called by muse, mutect2, varscan2
- ANK3 | c.1436C>A p.A479D | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.343); catalogued as COSV55072698; called by muse, mutect2, varscan2
- AP3M1 | c.904G>C p.G302R | Missense Mutation (SNP) | VAF 23/102 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.795); catalogued as COSV62332110; called by muse, mutect2, varscan2
- AP5B1 | c.2383G>A p.E795K | Missense Mutation (SNP) | VAF 23/90 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs376239404; called by muse, mutect2, varscan2
- APBB1IP | c.602G>C p.R201P | Missense Mutation (SNP) | VAF 24/99 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.722); catalogued as COSV63076096, COSV63076563; called by muse, mutect2, varscan2
- ARHGAP9 | c.649G>C p.D217H | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62723981; called by muse, mutect2, varscan2
- ATP10D | c.1058dup p.N354Qfs*6 | Frame Shift Ins (INS) | VAF 97/196 reads (49%) | catalogued as rs911237323; called by mutect2, pindel, varscan2
- ATP2B3 | c.2047G>T p.V683L | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.254); catalogued as COSV54856249; called by muse, mutect2, varscan2
- ATP8B4 | c.2616C>G p.F872L | Missense Mutation (SNP) | VAF 74/225 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); catalogued as COSV52721045; called by muse, mutect2, varscan2
- BICD2 | c.1028C>G p.S343C | Missense Mutation (SNP) | VAF 30/70 reads (43%) | SIFT tolerated (0.05); PolyPhen benign (0.03); catalogued as rs1313294851, COSV63550272; called by muse, mutect2, varscan2
- BRIP1 | c.2728G>C p.E910Q | Missense Mutation (SNP) | VAF 99/208 reads (48%) | SIFT tolerated (0.2); PolyPhen benign (0.192); catalogued as rs1007808618, COSV52005270; ClinVar: uncertain significance; called by muse, mutect2
- BRS3 | c.574C>G p.R192G | Missense Mutation (SNP) | VAF 38/92 reads (41%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as COSV65711205, COSV65711372; called by muse, mutect2, varscan2
- C1orf94 | c.901C>T p.P301S (on ENST00000488417 / NM_001134734.2; = p.P111S on NM_032884.5) | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT tolerated (0.59); PolyPhen benign (0.003); catalogued as rs556951025, COSV64914856; called by muse, mutect2, varscan2
- C5orf22 | c.323G>C p.R108T | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT tolerated (0.61); PolyPhen benign (0.037); catalogued as COSV57599507; called by muse, mutect2, varscan2
- C9 | c.1408A>G p.S470G | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.192); catalogued as COSV54679607; called by muse, mutect2, varscan2
- CADM1 | c.865C>G p.Q289E | Missense Mutation (SNP) | VAF 34/116 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV59018228; called by muse, mutect2, varscan2
- CAMK2D | c.890G>C p.R297T | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.255); catalogued as COSV56435953; called by muse, mutect2, varscan2
- CASD1 | c.1632C>T p.N544= | Splice Region (SNP) | VAF 10/28 reads (36%) | catalogued as rs376448411; called by mutect2, varscan2
- CCDC138 | c.422C>G p.S141W | Missense Mutation (SNP) | VAF 37/103 reads (36%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.747); catalogued as rs767526878, COSV54570301; called by muse, mutect2, varscan2
- CCR3 | c.47A>G p.Y16C | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.711); catalogued as COSV62464979; called by muse, mutect2, varscan2
- CCR5 | c.592A>G p.I198V | Missense Mutation (SNP) | VAF 116/253 reads (46%) | SIFT tolerated (0.46); PolyPhen benign (0.04); catalogued as COSV52752488; called by muse, mutect2, varscan2
- CD226 | c.438G>C p.K146N | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT tolerated (0.16); PolyPhen benign (0.011); catalogued as COSV54614674, COSV54616504, COSV99710753; called by muse, mutect2, varscan2
- CD3E | c.565G>C p.E189Q | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62346318; called by muse, mutect2, varscan2
- CEACAM8 | c.424C>T p.P142S | Missense Mutation (SNP) | VAF 33/100 reads (33%) | SIFT tolerated (0.62); PolyPhen benign (0.006); catalogued as rs146875157, COSV54990636; called by muse, mutect2, varscan2
- CEBPZ | c.2536G>C p.E846Q | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.021); catalogued as COSV52207698; called by muse, mutect2, varscan2
- CEP41 | c.1006G>C p.E336Q | Missense Mutation (SNP) | VAF 58/198 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.024); catalogued as COSV56220853; called by muse, mutect2, varscan2
- CEP78 | c.2036C>G p.S679C (on ENST00000424347 / NM_001349840.2; = p.S680C on NM_032171.3) | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.436); catalogued as COSV52849259; called by muse, mutect2, varscan2
- CFAP47 | c.1210G>A p.G404S | Missense Mutation (SNP) | VAF 23/99 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs1410326527, COSV52889160; called by muse, mutect2, varscan2
- CHAMP1 | c.728C>T p.S243L | Missense Mutation (SNP) | VAF 40/108 reads (37%) | SIFT tolerated (0.7); PolyPhen benign (0.003); catalogued as COSV63522886; called by muse, varscan2
- CHD4 | c.4582C>G p.P1528A (on ENST00000357008 / NM_001363606.2; = p.P1541A on NM_001273.5) | Missense Mutation (SNP) | VAF 21/91 reads (23%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.987); catalogued as COSV58907461; called by muse, mutect2, varscan2
- CHD4 | c.3958C>G p.L1320V (on ENST00000357008 / NM_001363606.2; = p.L1333V on NM_001273.5) | Missense Mutation (SNP) | VAF 91/272 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV58907478; called by muse, mutect2, varscan2
- CHD5 | c.1751G>A p.R584H | Missense Mutation (SNP) | VAF 23/95 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs141210110, COSV99314074; called by mutect2, varscan2
- CHRM3 | c.1751G>A p.R584H | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as rs532452227, COSV55097295; called by mutect2, varscan2
- CIB4 | c.405G>T p.M135I | Missense Mutation (SNP) | VAF 27/106 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV56602676; called by muse, mutect2, varscan2
- COL5A3 | c.446G>C p.R149P | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV53416118; called by muse, mutect2, varscan2
- COMMD9 | c.356C>G p.S119C | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54672965; called by muse, mutect2, varscan2
- CPXCR1 | c.166G>T p.A56S | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated (0.96); PolyPhen benign (0); catalogued as COSV52163659; called by muse, mutect2, varscan2
- CRB2 | c.455C>T p.S152L | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63504640; called by muse, mutect2, varscan2
- CTCF | c.1163G>A p.S388N | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs911815810, COSV50492256; called by muse, mutect2, varscan2
- CTTNBP2 | c.1624C>T p.P542S | Missense Mutation (SNP) | VAF 39/151 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50440115; called by muse, mutect2, varscan2
- CTTNBP2 | c.252C>G p.F84L | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.863); catalogued as COSV50440380; called by muse, mutect2, varscan2
- CYP26C1 | c.748G>T p.A250S | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.72); catalogued as COSV53329685, COSV99592593; called by muse, mutect2, varscan2
- DCAF12L1 | c.826G>T p.E276* | Nonsense Mutation (SNP) | VAF 12/40 reads (30%) | catalogued as COSV64421797; called by mutect2, varscan2
- DCLK2 | c.1534G>A p.V512M | Missense Mutation (SNP) | VAF 96/169 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs200547939, COSV56209131; called by mutect2, varscan2
- DDAH1 | c.585G>C p.Q195H | Missense Mutation (SNP) | VAF 53/151 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.049); catalogued as COSV52306182, COSV99394613; called by muse, mutect2, varscan2
- DDI1 | c.956C>G p.S319C | Missense Mutation (SNP) | VAF 35/125 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV56387560; called by muse, mutect2, varscan2
- DLG2 | c.1127C>G p.S376* | Nonsense Mutation (SNP) | VAF 22/79 reads (28%) | catalogued as COSV99713652; called by muse, mutect2, varscan2
- DLL3 | c.952G>C p.D318H | Missense Mutation (SNP) | VAF 41/116 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52696010; called by muse, mutect2, varscan2
- DNAH5 | c.1179C>G p.I393M | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.017); catalogued as COSV54207534, COSV54242204; called by muse, mutect2, varscan2
- DNAH7 | c.9034G>T p.V3012L | Missense Mutation (SNP) | VAF 36/51 reads (71%) | SIFT tolerated (0.1); PolyPhen benign (0.019); catalogued as COSV56777055; called by muse, mutect2, varscan2
- DNAJC13 | c.2014G>C p.E672Q | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT tolerated (0.37); PolyPhen benign (0.021); catalogued as COSV53455176; called by muse, mutect2, varscan2
- DNAJC6 | c.2360C>G p.S787C | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.141); catalogued as rs947409137, COSV54779273; called by muse, mutect2, varscan2
- DNM1 | c.922G>C p.E308Q | Missense Mutation (SNP) | VAF 22/89 reads (25%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.991); catalogued as COSV57854681; called by muse, mutect2, varscan2
- DOCK1 | c.922G>A p.E308K | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.157); catalogued as COSV54751894; called by muse, mutect2, varscan2
- DOCK8 | c.955C>T p.H319Y | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.414); catalogued as COSV66635057; called by muse, mutect2, varscan2
- DYNLL1 | c.180G>C p.R60S | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.158); catalogued as COSV54359959; called by muse, mutect2, varscan2
- E2F8 | c.475G>A p.D159N | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs751632122, COSV51465200; called by mutect2, varscan2
- EEF1AKMT4-ECE2 | c.1248G>C p.Q416H | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV62569714; called by muse, mutect2, varscan2
- EHBP1 | c.1981G>A p.G661R | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.682); catalogued as COSV50429262; called by muse, mutect2, varscan2
- EIF4ENIF1 | c.2270C>A p.S757Y | Missense Mutation (SNP) | VAF 46/174 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.119); catalogued as rs1447506227, COSV57517351; called by muse, mutect2, varscan2
- ELAPOR2 | c.1400-1G>A p.X467_splice (on ENST00000450689 / NM_001142749.3; = p.X300_splice on NM_152748.4 and 2 other RefSeq transcripts) | Splice Site (SNP) | VAF 12/27 reads (44%) | catalogued as COSV51886294, COSV51889819; called by muse, mutect2, varscan2
- EP300 | c.2245A>G p.M749V | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.168); catalogued as rs370478867; ClinVar: likely benign; called by muse, mutect2, varscan2
- ETFBKMT | c.344G>A p.R115K | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated (0.33); PolyPhen benign (0.044); catalogued as COSV63189470; called by muse, mutect2, varscan2
- EYA4 | c.661del p.S221Vfs*74 | Frame Shift Del (DEL) | VAF 21/63 reads (33%) | catalogued as COSV62057933; called by mutect2, pindel, varscan2
- FAM234B | c.955G>A p.V319I | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.414); catalogued as COSV52196396; called by muse, mutect2, varscan2
- FAM47B | c.1594C>T p.R532C | Missense Mutation (SNP) | VAF 34/113 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.01); catalogued as rs773159030, COSV61452348; called by muse, mutect2, varscan2
- FANCM | c.2201C>G p.S734C | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.01); catalogued as COSV57504373; called by muse, mutect2, varscan2
- FAT1 | c.10679C>G p.S3560* | Nonsense Mutation (SNP) | VAF 31/51 reads (61%) | catalogued as COSV71675330; called by muse, mutect2, varscan2
- FBXL17 | c.1901G>A p.G634E | Missense Mutation (SNP) | VAF 32/143 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62857609; called by muse, mutect2, varscan2
- FER | c.2120G>A p.R707H | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs151332661, COSV55300024; called by mutect2, varscan2
- FLNA | c.7166C>T p.A2389V (on ENST00000369850 / NM_001110556.2; = p.A2381V on NM_001456.3) | Missense Mutation (SNP) | VAF 25/90 reads (28%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.456); catalogued as COSV61048457; called by muse, varscan2
- FLNB | c.4615G>T p.D1539Y | Missense Mutation (SNP) | VAF 57/136 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.732); catalogued as COSV55889110; called by muse, varscan2
- FLRT3 | c.715G>A p.A239T | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT tolerated (0.45); PolyPhen benign (0.011); catalogued as COSV54024271; called by muse, mutect2, varscan2
- FMO5 | c.1096C>G p.L366V | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.85); catalogued as COSV54209268; called by muse, varscan2
- FMO5 | c.1015C>G p.L339V | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.855); catalogued as COSV54209290; called by muse, varscan2
- FOXRED2 | c.1384A>C p.N462H | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.711); catalogued as COSV53401201; called by muse, mutect2, varscan2
- FYN | c.328C>G p.Q110E | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT tolerated (0.45); PolyPhen benign (0.006); catalogued as COSV57612610, COSV57617681, COSV57618360; called by muse, mutect2, varscan2
- GABBR2 | c.1833C>G p.I611M | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52313765; called by muse, mutect2, varscan2
- GANAB | c.2074C>T p.Q692* | Nonsense Mutation (SNP) | VAF 42/146 reads (29%) | catalogued as COSV100648105; called by muse, varscan2
- GFM1 | c.110C>T p.S37L | Missense Mutation (SNP) | VAF 24/92 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.184); catalogued as COSV51834679; called by muse, mutect2, varscan2
- GLI1 | c.2932G>C p.A978P | Missense Mutation (SNP) | VAF 35/105 reads (33%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.143); catalogued as COSV57365193; called by muse, mutect2, varscan2
- GPC6 | c.70G>A p.D24N | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT tolerated (0.24); PolyPhen benign (0.179); catalogued as COSV65526064; called by muse, varscan2
- GPR4 | c.449C>G p.S150W | Missense Mutation (SNP) | VAF 24/104 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0.188); catalogued as COSV59917035, COSV59917822; called by muse, mutect2, varscan2
- GPR50 | c.1412C>G p.S471C | Missense Mutation (SNP) | VAF 150/455 reads (33%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.001); catalogued as COSV54441525, COSV99506753; called by muse, varscan2
- GPR50 | c.1476C>A p.F492L | Missense Mutation (SNP) | VAF 94/302 reads (31%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0); catalogued as COSV54441541; called by muse, varscan2
- GRM1 | c.1630T>A p.C544S | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV51224702; called by muse, varscan2
- GSTP1 | c.437G>T p.G146V | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.715); catalogued as COSV66992706; called by muse, varscan2
- GTF3C1 | c.5765C>T p.A1922V | Missense Mutation (SNP) | VAF 55/185 reads (30%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs764407120, COSV62243163; called by muse, mutect2, varscan2
- GUCY2C | c.301G>A p.E101K | Missense Mutation (SNP) | VAF 28/111 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as COSV53793637; called by muse, mutect2, varscan2
- HAO1 | c.972G>C p.Q324H | Missense Mutation (SNP) | VAF 78/184 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.279); catalogued as COSV66493211; called by muse, mutect2, varscan2
- HDC | c.1442C>T p.S481F | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as COSV51076294; called by muse, mutect2, varscan2
- HDLBP | c.1860G>C p.E620D | Missense Mutation (SNP) | VAF 67/229 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.331); catalogued as COSV60499266; called by muse, mutect2, varscan2
- HIP1 | c.1189G>C p.E397Q | Missense Mutation (SNP) | VAF 42/189 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.953); catalogued as COSV61189401; called by muse, mutect2, varscan2
- HPF1 | c.124G>A p.E42K | Missense Mutation (SNP) | VAF 21/34 reads (62%) | SIFT tolerated (0.26); PolyPhen benign (0.047); catalogued as rs1358076733, COSV66422584; called by muse, mutect2, varscan2
- IGDCC3 | c.250G>T p.E84* | Nonsense Mutation (SNP) | VAF 8/32 reads (25%) | catalogued as COSV100031529; called by mutect2, varscan2
- IGHA2 | c.491G>A p.R164H | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.033); catalogued as rs781940822; called by muse, mutect2, varscan2
- INPP4B | c.2746G>C p.E916Q | Missense Mutation (SNP) | VAF 45/66 reads (68%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.9); catalogued as COSV53737790; called by muse, mutect2, varscan2
- IQCB1 | c.1150C>T p.R384W | Missense Mutation (SNP) | VAF 50/276 reads (18%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.988); catalogued as rs760548277, COSV60438886; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- IRF1 | c.954C>G p.I318M | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.57); PolyPhen benign (0.426); catalogued as COSV55377992; called by muse, mutect2, varscan2
- IRF2BP1 | c.581C>G p.S194C | Missense Mutation (SNP) | VAF 34/130 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.253); catalogued as COSV56194594; called by muse, mutect2, varscan2
- IRS4 | c.3662G>A p.R1221Q | Missense Mutation (SNP) | VAF 84/295 reads (28%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.001); catalogued as rs780907100, COSV64534421, COSV64535204, COSV64535843; called by muse, mutect2, varscan2
- ISLR2 | c.13C>T p.R5W | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs1394661016, COSV62301583; called by muse, mutect2, varscan2
- ITIH6 | c.3644G>T p.R1215M | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.69); catalogued as COSV54492293; called by mutect2, varscan2
- JARID2 | c.1250C>T p.S417L | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.015); catalogued as COSV59194521; called by muse, mutect2, varscan2
- KCNA1 | c.580G>A p.D194N | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs1299794605, COSV66838279; called by muse, mutect2, varscan2
- KCNH5 | c.678C>G p.F226L | Missense Mutation (SNP) | VAF 30/62 reads (48%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.574); catalogued as COSV59756732; called by muse, mutect2, varscan2
- KCNQ2 | c.1038C>G p.F346L | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT tolerated (0.69); PolyPhen benign (0.232); catalogued as COSV60437511; called by muse, mutect2, varscan2
- KCNQ3 | c.1396T>G p.L466V | Missense Mutation (SNP) | VAF 34/118 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.055); catalogued as COSV66477479; called by muse, mutect2, varscan2
- KEAP1 | c.652G>C p.E218Q | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.812); catalogued as COSV50261023, COSV50643018; called by muse, varscan2
- KIF14 | c.3272C>T p.S1091L | Missense Mutation (SNP) | VAF 51/141 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV66260253, COSV66263168; called by muse, mutect2, varscan2
- KIF23 | c.1281G>A p.M427I | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.955); catalogued as rs149564859, COSV52981823; called by muse, mutect2, varscan2
- KLK6 | c.76G>A p.G26R | Missense Mutation (SNP) | VAF 35/54 reads (65%) | SIFT tolerated (0.37); PolyPhen benign (0.023); catalogued as rs200733164, COSV59565508; called by muse, mutect2, varscan2
- LRRCC1 | c.1600C>A p.Q534K | Missense Mutation (SNP) | VAF 31/118 reads (26%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.632); catalogued as COSV64484754; called by muse, varscan2
- LRRIQ1 | c.279G>A p.M93I | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (0.29); PolyPhen benign (0.039); catalogued as COSV67813590; called by mutect2, varscan2
- LRRK2 | c.5377C>T p.P1793S | Missense Mutation (SNP) | VAF 42/166 reads (25%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as COSV54163557; called by muse, mutect2, varscan2
- LY6G6F-LY6G6D | c.1039C>G p.L347V | Missense Mutation (SNP) | VAF 39/155 reads (25%) | SIFT tolerated, low confidence (0.87); PolyPhen benign (0); catalogued as COSV65419963; called by muse, mutect2, varscan2
- MACC1 | c.116-1G>A p.X39_splice | Splice Site (SNP) | VAF 13/42 reads (31%) | catalogued as COSV60545136; called by muse, mutect2, varscan2
- MAP2K3 | c.328G>A p.D110N (on ENST00000342679 / NM_145109.3; = p.D81N on NM_002756.4) | Missense Mutation (SNP) | VAF 11/104 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV57562204; called by muse, mutect2, varscan2
- MB21D2 | c.931C>G p.Q311E | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.403); catalogued as rs988241015, COSV66661548, COSV66661553; called by muse, mutect2, varscan2
- MCL1 | c.559C>T p.R187W | Missense Mutation (SNP) | VAF 25/78 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.735); catalogued as COSV57189959; called by muse, mutect2, varscan2
- MDN1 | c.11810C>T p.P3937L | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV65526882; called by muse, mutect2, varscan2
- MED13 | c.694T>A p.L232I | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); catalogued as COSV63228678; called by muse, mutect2, varscan2
- MEGF9 | c.412C>G p.Q138E | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.005); catalogued as rs980351465, COSV64236928; called by muse, mutect2, varscan2
- MERTK | c.685A>G p.I229V | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.997); catalogued as COSV54933247; called by muse, mutect2, varscan2
- MIF4GD | c.433G>C p.E145Q (on ENST00000325102 / NM_001370592.1; = p.E179Q on NM_020679.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/92 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as COSV55453808; called by muse, mutect2, varscan2
- MMS22L | c.2210C>T p.S737L | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.033); catalogued as rs1041979811, COSV51524411; called by mutect2, varscan2
- MUC5AC | c.14797G>A p.D4933N | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs369198434; called by muse, mutect2, varscan2
- MVP | c.1234G>A p.E412K | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV62421711; called by muse, mutect2, varscan2
- NEMP1 | c.1261G>A p.E421K (on ENST00000300128 / NM_001130963.2; = p.E348K on NM_015257.3) | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.202); catalogued as COSV55663941, COSV55665266; called by muse, varscan2
- NEMP1 | c.1213G>A p.E405K (on ENST00000300128 / NM_001130963.2; = p.E332K on NM_015257.3) | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.818); catalogued as COSV55663954; called by muse, varscan2
- NEUROD6 | c.184G>A p.E62K | Missense Mutation (SNP) | VAF 53/139 reads (38%) | SIFT tolerated (0.4); PolyPhen benign (0.034); catalogued as COSV51772774; called by muse, varscan2
- NHLRC3 | c.707G>C p.R236T | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101099060, COSV65463287; called by muse, mutect2, varscan2
- NKAP | c.242G>C p.R81T | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.245); catalogued as COSV65056691; called by muse, varscan2
- NPAS4 | c.1714G>A p.E572K | Missense Mutation (SNP) | VAF 39/164 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as rs749596623, COSV60651859; called by muse, mutect2, varscan2
- NPHS1 | c.3343G>A p.E1115K | Missense Mutation (SNP) | VAF 33/88 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.588); catalogued as CM098888, COSV62289225; called by muse, mutect2, varscan2
- NR1D1 | c.251C>G p.S84* | Nonsense Mutation (SNP) | VAF 15/54 reads (28%) | catalogued as COSV52842082; called by muse, mutect2, varscan2
- NRAP | c.4988G>C p.R1663T (on ENST00000359988 / NM_001322945.2; = p.R1628T on NM_006175.4) | Missense Mutation (SNP) | VAF 31/95 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as COSV63492838; called by muse, mutect2, varscan2
- NTM | c.526+1G>A p.X176_splice | Splice Site (SNP) | VAF 39/139 reads (28%) | catalogued as COSV66187967; called by muse, mutect2, varscan2
- OGFOD1 | c.1420G>A p.E474K | Missense Mutation (SNP) | VAF 48/124 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.328); catalogued as rs1352768511, COSV60201173; called by muse, varscan2
- OR13C3 | c.652G>T p.A218S | Missense Mutation (SNP) | VAF 27/107 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.789); catalogued as COSV66166090; called by muse, mutect2, varscan2
- OR2D3 | c.962T>C p.V321A | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs373498599; called by muse, varscan2
- OR52L1 | c.14C>G p.S5C | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.839); catalogued as COSV59988392; called by muse, mutect2, varscan2
- OR5A1 | c.638C>A p.S213* | Nonsense Mutation (SNP) | VAF 48/156 reads (31%) | catalogued as rs574597111, COSV57375852; called by muse, varscan2
- OR8B4 | c.53C>T p.S18L | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.146); catalogued as rs778997504, COSV62069183, COSV62070254; called by muse, mutect2, varscan2
- OTOP3 | c.92G>A p.R31Q | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as rs761263942; called by mutect2, varscan2
- P2RY10 | c.585G>T p.L195F | Missense Mutation (SNP) | VAF 21/87 reads (24%) | SIFT tolerated (0.29); PolyPhen benign (0.285); catalogued as COSV50683818, COSV99409017; called by muse, mutect2, varscan2
- PAK5 | c.548C>G p.S183C | Missense Mutation (SNP) | VAF 70/173 reads (40%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.087); catalogued as COSV62029892, COSV62033799; called by muse, mutect2, varscan2
- PCDH11X | c.3694C>T p.H1232Y | Missense Mutation (SNP) | VAF 42/139 reads (30%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0.011); catalogued as COSV53455071, COSV53509017; called by muse, mutect2, varscan2
- PCDH19 | c.20C>T p.P7L | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs1350725154; called by mutect2, varscan2
- PCDHGA12 | c.2625G>C p.L875F | Missense Mutation (SNP) | VAF 40/182 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as COSV52761214, COSV52762387; called by muse, mutect2, varscan2
- PDIA2 | c.786C>G p.F262L | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV51990710; called by muse, mutect2, varscan2
- PDLIM5 | c.1186A>C p.T396P | Missense Mutation (SNP) | VAF 34/79 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58750862; called by muse, mutect2, varscan2
- PFKFB3 | c.321G>C p.L107F | Missense Mutation (SNP) | VAF 39/114 reads (34%) | PolyPhen probably damaging (0.991); catalogued as COSV57987249, COSV57991530; called by muse, mutect2, varscan2
- PIK3CA | c.1352G>T p.G451V | Missense Mutation (SNP) | VAF 32/138 reads (23%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.858); catalogued as COSV55964100; called by mutect2, varscan2
- PLAGL2 | c.1242C>A p.F414L | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated (0.52); PolyPhen benign (0.026); catalogued as COSV55789242; called by mutect2, varscan2
- PLEC | c.12815C>A p.S4272Y (on ENST00000322810 / NM_201380.4; = p.S4162Y on NM_000445.5) | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59621926, COSV59671437; called by mutect2, varscan2
- PLK3 | c.1308T>G p.C436W | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.474); catalogued as COSV59500632; called by muse, mutect2, varscan2
- PPM1F | c.910G>A p.E304K | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.728); catalogued as rs1174030342, COSV54283742; called by muse, mutect2, varscan2
- PPP2R5A | c.1059C>G p.F353L | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54818038; called by muse, mutect2, varscan2
- PRG4 | c.3789G>C p.K1263N | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63356122; called by muse, mutect2, varscan2
- PRPS1 | c.946G>T p.V316F | Missense Mutation (SNP) | VAF 40/126 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.676); catalogued as COSV65054569; called by muse, mutect2, varscan2
- PRRG2 | c.226G>A p.E76K | Missense Mutation (SNP) | VAF 28/92 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1169566743, COSV55870969; called by muse, mutect2, varscan2
- PTPRC | c.340G>A p.D114N | Missense Mutation (SNP) | VAF 42/143 reads (29%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.005); catalogued as COSV61417919; called by muse, mutect2, varscan2
- RBM14 | c.325G>C p.D109H | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59559178, COSV59560115; called by muse, mutect2, varscan2
- RECK | c.1852G>A p.E618K | Missense Mutation (SNP) | VAF 34/158 reads (22%) | SIFT tolerated (0.54); PolyPhen benign (0.119); catalogued as COSV65035986; called by muse, mutect2, varscan2
- ROBO4 | c.590C>T p.A197V | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT tolerated (0.54); PolyPhen benign (0.017); catalogued as COSV60626539; called by muse, mutect2, varscan2
- ROS1 | c.4742C>G p.S1581C | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as COSV63859307; called by muse, mutect2, varscan2
- RPS18 | c.151G>A p.D51N | Missense Mutation (SNP) | VAF 40/133 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.439); catalogued as COSV65852020, COSV65852138; called by muse, mutect2, varscan2
- RRAGA | c.661G>C p.E221Q | Missense Mutation (SNP) | VAF 41/174 reads (24%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as COSV65843862; called by muse, mutect2, varscan2
- RTN2 | c.142G>T p.E48* | Nonsense Mutation (SNP) | VAF 25/57 reads (44%) | catalogued as COSV99838828; called by muse, mutect2, varscan2
- RUSC2 | c.4478C>T p.S1493F | Missense Mutation (SNP) | VAF 29/126 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.078); catalogued as COSV63429739; called by muse, mutect2, varscan2
- RYR1 | c.14645C>T p.T4882M | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs193922884, CM081417, COSV62091711; ClinVar: conflicting interpretations of pathogenicity / pathogenic; called by muse, mutect2, varscan2
- SCN9A | c.239C>T p.P80L | Missense Mutation (SNP) | VAF 40/68 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV57618531; called by muse, mutect2, varscan2
- SEMA5B | c.696C>G p.D232E | Missense Mutation (SNP) | VAF 14/116 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as COSV52104367; called by muse, mutect2, varscan2
- SERPINA4 | c.864G>C p.E288D | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.041); catalogued as rs768080063, COSV54071072; called by muse, mutect2, varscan2
- SERPINH1 | c.272C>T p.S91L | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.532); catalogued as rs750020039, COSV63998316; called by mutect2, varscan2
- SH2B1 | c.1015G>C p.D339H | Missense Mutation (SNP) | VAF 56/214 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59461657, COSV59465402; called by muse, mutect2, varscan2
- SHROOM4 | c.4397G>C p.R1466P | Missense Mutation (SNP) | VAF 28/63 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56789594, COSV56794468; called by muse, mutect2, varscan2
- SIAE | c.467C>T p.S156F | Missense Mutation (SNP) | VAF 54/174 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.158); catalogued as COSV55014920; called by muse, mutect2, varscan2
- SLC27A4 | c.1144G>C p.E382Q | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV55961154; called by muse, mutect2, varscan2
- SLC30A6 | c.466C>G p.R156G | Missense Mutation (SNP) | VAF 34/131 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.006); catalogued as rs148435831, COSV50873613; called by muse, mutect2, varscan2
- SLC46A2 | c.213G>C p.Q71H | Missense Mutation (SNP) | VAF 89/204 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV65289992, COSV65290272; called by muse, mutect2, varscan2
- SLC7A14 | c.727G>A p.E243K | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT tolerated (0.45); PolyPhen benign (0.257); catalogued as COSV51577519, COSV51586829; called by muse, mutect2, varscan2
- SMR3B | c.173G>C p.R58T | Missense Mutation (SNP) | VAF 35/87 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.895); catalogued as COSV59228355, COSV59229278; called by muse, mutect2, varscan2
- SNX30 | c.335G>C p.R112T | Missense Mutation (SNP) | VAF 36/127 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.426); catalogued as COSV65293784; called by muse, mutect2, varscan2
- SORCS3 | c.2291G>T p.S764I | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.418); catalogued as COSV63795881, COSV63797138; called by muse, mutect2, varscan2
- SORD | c.1006G>C p.E336Q | Missense Mutation (SNP) | VAF 25/126 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.131); catalogued as COSV99980346; called by muse, mutect2, varscan2
- SPANXN5 | c.191C>G p.S64* | Nonsense Mutation (SNP) | VAF 41/144 reads (28%) | catalogued as rs1556775715, COSV64968809; called by muse, mutect2, varscan2
- SRPK3 | c.562G>A p.V188M | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs374171969, COSV54209205; called by mutect2, varscan2
- SUGP1 | c.1152G>C p.K384N | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs778539130, COSV55923050; called by muse, mutect2, varscan2
- SYNE2 | c.13264C>G p.Q4422E | Missense Mutation (SNP) | VAF 42/101 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as COSV59961978; called by muse, mutect2, varscan2
- SYNPO2L | c.2017G>A p.E673K (on ENST00000394810 / NM_001114133.3; = p.E449K on NM_024875.5) | Missense Mutation (SNP) | VAF 49/178 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs1281904778, COSV65738355; called by muse, varscan2
- SYTL3 | c.874G>C p.D292H (on ENST00000611299 / NM_001242394.1; = p.D224H on NM_001009991.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.082); catalogued as COSV51913431; called by muse, varscan2
- SYTL3 | c.1017G>C p.K339N (on ENST00000611299 / NM_001242394.1; = p.K271N on NM_001009991.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.2); catalogued as COSV51913449, COSV99792510; called by muse, varscan2
- TBC1D10C | c.424C>G p.Q142E | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV56704388; called by muse, mutect2, varscan2
- TCEAL2 | c.553A>G p.K185E | Missense Mutation (SNP) | VAF 51/203 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.802); catalogued as rs781078952, COSV61197591; called by muse, mutect2, varscan2
- TECTA | c.328G>C p.E110Q | Missense Mutation (SNP) | VAF 31/92 reads (34%) | SIFT tolerated (0.28); PolyPhen benign (0.103); catalogued as COSV50695664, COSV50763200; called by muse, mutect2, varscan2
- TEX10 | c.1274C>G p.S425C | Missense Mutation (SNP) | VAF 44/148 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.215); catalogued as COSV66517538; called by muse, mutect2, varscan2
- TGM1 | c.674G>T p.R225L | Missense Mutation (SNP) | VAF 22/91 reads (24%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.736); catalogued as CM092040, CM981915, COSV52862902, COSV52864543; called by muse, mutect2, varscan2
- THAP8 | c.673-1G>C p.X225_splice | Splice Site (SNP) | VAF 14/56 reads (25%) | catalogued as rs74384706; called by muse, mutect2, varscan2
- THSD4 | c.2193C>G p.C731W | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55968743, COSV55978727; called by muse, mutect2, varscan2
- TLE4 | c.1836G>A p.V612= | Splice Region (SNP) | VAF 11/55 reads (20%) | catalogued as COSV54637653, COSV99513181; called by muse, mutect2, varscan2
- TNPO3 | c.2200C>G p.Q734E | Missense Mutation (SNP) | VAF 23/79 reads (29%) | SIFT tolerated (0.96); PolyPhen benign (0.005); catalogued as COSV55278983, COSV55284822; called by muse, mutect2, varscan2
- TNS4 | c.611C>G p.S204C | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as COSV54187073; called by muse, mutect2, varscan2
- TRA2A | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 21/61 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.019); catalogued as COSV51718131; called by mutect2, varscan2
- TRIM21 | c.114A>T p.E38D | Missense Mutation (SNP) | VAF 40/115 reads (35%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.596); catalogued as COSV54345526; called by muse, mutect2, varscan2
- TTC13 | c.2086G>A p.G696R | Missense Mutation (SNP) | VAF 40/149 reads (27%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.98); catalogued as rs748856539, COSV64169336; called by muse, mutect2, varscan2
- TTLL10 | c.1378G>C p.D460H (on ENST00000379289 / NM_001130045.2; = p.D387H on NM_153254.3) | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV64960762; called by muse, mutect2, varscan2
- TTN | c.74879G>T p.G24960V (on ENST00000591111; = p.G17536V on NM_003319.4) | Missense Mutation (SNP) | VAF 56/193 reads (29%) | PolyPhen probably damaging (0.934); catalogued as COSV60231236; called by muse, mutect2, varscan2
- UBE2J1 | c.767G>A p.R256Q | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.163); catalogued as rs202016441, COSV101470290; called by muse, mutect2, varscan2
- UBE3B | c.703C>G p.L235V | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.343); catalogued as COSV55096413; called by muse, varscan2
- UBE3B | c.1194C>A p.F398L | Missense Mutation (SNP) | VAF 39/129 reads (30%) | SIFT tolerated (0.39); PolyPhen benign (0.038); catalogued as COSV55096462; called by muse, mutect2, varscan2
- UBE3B | c.2393C>G p.S798C | Missense Mutation (SNP) | VAF 31/138 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV61076498; called by muse, mutect2, varscan2
- WAC | c.1865G>A p.R622Q | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs759496172, COSV61568766, COSV61569330; called by mutect2, varscan2
- XRN1 | c.88G>C p.D30H | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53815859; called by muse, mutect2, varscan2
- YY1AP1 | c.268G>A p.E90K (on ENST00000295566 / NM_139118.2; = p.E13K on NM_018253.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.828); catalogued as rs1427756819, COSV55123679; called by muse, mutect2, varscan2
- ZBTB2 | c.415G>A p.D139N | Missense Mutation (SNP) | VAF 32/107 reads (30%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); catalogued as COSV57313575; called by muse, mutect2, varscan2
- ZBTB8A | c.639G>C p.L213F | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.792); catalogued as COSV57143578; called by muse, mutect2, varscan2
- ZDHHC19 | c.839del p.L280Rfs*73 | Frame Shift Del (DEL) | VAF 10/63 reads (16%) | catalogued as COSV56349562; called by mutect2, pindel, varscan2
- ZMYM3 | c.754G>A p.E252K | Missense Mutation (SNP) | VAF 18/90 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.931); catalogued as COSV58739717; called by muse, varscan2
- ZNF280C | c.530C>G p.S177C | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.16); catalogued as COSV63969162, COSV63969530; called by muse, varscan2
- ZNF439 | c.931C>T p.R311C | Missense Mutation (SNP) | VAF 19/88 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as rs778004710, COSV58310432; called by muse, mutect2, varscan2
- ZNF511 | c.663G>T p.R221S | Missense Mutation (SNP) | VAF 21/115 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.349); catalogued as COSV62920449; called by muse, mutect2, varscan2
- ZNF655 | c.73G>C p.E25Q | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.863); catalogued as COSV53159522; called by muse, mutect2, varscan2
- ZNF664 | c.131C>T p.S44L | Missense Mutation (SNP) | VAF 23/114 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.099); catalogued as COSV61878370; called by muse, mutect2, varscan2
- ZNF768 | c.1553G>A p.C518Y | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV63323547; called by mutect2, varscan2
- ZSCAN20 | c.1354G>A p.E452K | Missense Mutation (SNP) | VAF 34/96 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.06); catalogued as COSV63683904; called by muse, mutect2, varscan2
- ZSWIM8 | c.2894G>A p.G965D (on ENST00000605216 / NM_001242487.2; = p.G970D on NM_015037.3) | Missense Mutation (SNP) | VAF 50/172 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67133859; called by muse, mutect2, varscan2
- AFF3 | c.3344G>A p.G1115E | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.954); called by muse, mutect2
- ATP8B4 | c.3374C>G p.S1125* | Nonsense Mutation (SNP) | VAF 21/78 reads (27%) | called by muse, mutect2, varscan2
- CAMSAP2 | c.88_109del p.A30Pfs*67 | Frame Shift Del (DEL) | VAF 12/86 reads (14%) | called by mutect2, pindel
- CATSPERG | c.1825G>A p.E609K | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.503); called by mutect2, varscan2
- CCNL1 | c.374del p.F125Sfs*22 | Frame Shift Del (DEL) | VAF 12/61 reads (20%) | called by mutect2, pindel, varscan2
- CDKN2A | c.290_300del p.L97Rfs*19 | Frame Shift Del (DEL) | VAF 6/32 reads (19%) | called by mutect2, pindel
- GLUD2 | c.878del p.L293* | Frame Shift Del (DEL) | VAF 33/145 reads (23%) | called by mutect2, pindel, varscan2
- GPC5 | c.1399C>T p.Q467* | Nonsense Mutation (SNP) | VAF 8/25 reads (32%) | called by mutect2, varscan2
- IFT88 | c.886C>T p.Q296* (on ENST00000319980 / NM_001318493.2; = p.Q287* on NM_006531.5 and 9 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 14/68 reads (21%) | called by mutect2, varscan2
- ITGAE | c.884C>G p.S295* | Nonsense Mutation (SNP) | VAF 45/106 reads (42%) | called by muse, mutect2, varscan2
- IWS1 | c.1504G>T p.E502* | Nonsense Mutation (SNP) | VAF 24/90 reads (27%) | called by muse, mutect2, varscan2
- LILRA2 | c.317C>G p.S106* | Nonsense Mutation (SNP) | VAF 15/46 reads (33%) | called by muse, mutect2, varscan2
- MTHFD1L | c.475C>T p.Q159* | Nonsense Mutation (SNP) | VAF 12/50 reads (24%) | called by muse, mutect2, varscan2
- PLEC | c.3775C>G p.L1259V (on ENST00000322810 / NM_201380.4; = p.L1149V on NM_000445.5) | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT tolerated (0.26); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PPP1R12C | c.1069C>T p.Q357* | Nonsense Mutation (SNP) | VAF 20/64 reads (31%) | called by muse, mutect2, varscan2
- RYR2 | c.8727C>G p.D2909E | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (0.26); PolyPhen benign (0.293); called by muse, mutect2
- SAMHD1 | c.1281dup p.L428Sfs*8 | Frame Shift Ins (INS) | VAF 39/109 reads (36%) | called by mutect2, pindel, varscan2
- SPEN | c.2268C>G p.Y756* | Nonsense Mutation (SNP) | VAF 28/98 reads (29%) | called by muse, mutect2, varscan2
- SSBP2 | c.198-1G>C p.X66_splice | Splice Site (SNP) | VAF 23/50 reads (46%) | called by muse, mutect2
- TNRC6A | c.4120C>T p.Q1374* | Nonsense Mutation (SNP) | VAF 29/108 reads (27%) | called by muse, mutect2, varscan2
- ZNF479 | c.232A>T p.K78* | Nonsense Mutation (SNP) | VAF 32/130 reads (25%) | called by mutect2, varscan2
- ZNF605 | c.1189G>A p.D397N | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- ACAN | c.6531G>A p.V2177= | Silent (SNP) | VAF 20/84 reads (24%) | catalogued as COSV61365916; called by muse, mutect2, varscan2
- ACD | c.1284G>A p.Q428= (on ENST00000620338; = p.Q339= on NM_022914.3) | Silent (SNP) | VAF 16/46 reads (35%) | catalogued as COSV54669333; called by muse, varscan2
- ACP6 | c.798C>T p.S266= | Silent (SNP) | VAF 25/78 reads (32%) | catalogued as COSV65077585; called by muse, mutect2, varscan2
- ADNP2 | c.732G>A p.E244= | Silent (SNP) | VAF 13/58 reads (22%) | catalogued as COSV51538282, COSV51541247; called by muse, mutect2, varscan2
- AMPH | c.1737C>T p.S579= | Silent (SNP) | VAF 14/39 reads (36%) | catalogued as rs1394615761, COSV57742797; called by mutect2, varscan2
- ANGEL1 | c.1119C>T p.L373= | Silent (SNP) | VAF 66/144 reads (46%) | catalogued as rs561771867, COSV51874704; called by muse, mutect2, varscan2
- ANKH | c.870C>T p.Y290= | Silent (SNP) | VAF 19/55 reads (35%) | catalogued as rs111688928, COSV52484260; called by mutect2, varscan2
- APOB | c.11523T>C p.N3841= | Silent (SNP) | VAF 34/110 reads (31%) | catalogued as COSV51945540; called by muse, mutect2, varscan2
- ARFGEF1 | c.5353C>T p.L1785= | Silent (SNP) | VAF 16/64 reads (25%) | catalogued as COSV51589614; called by muse, mutect2, varscan2
- BCORL1 | c.1914G>A p.Q638= | Silent (SNP) | VAF 29/97 reads (30%) | catalogued as COSV54402388; called by muse, mutect2, varscan2
- BICD2 | c.696C>A p.L232= | Silent (SNP) | VAF 46/118 reads (39%) | catalogued as COSV63550281; called by muse, varscan2
- CCDC134 | c.345C>T p.F115= | Silent (SNP) | VAF 32/129 reads (25%) | catalogued as rs762153967, COSV55388702; called by muse, mutect2, varscan2
- CDS2 | c.1164G>C p.L388= | Silent (SNP) | VAF 46/219 reads (21%) | catalogued as COSV66897209; called by muse, mutect2, varscan2
- CFAP69 | c.237G>A p.Q79= | Silent (SNP) | VAF 11/40 reads (28%) | catalogued as COSV60187276; called by muse, mutect2, varscan2
- CHTF18 | c.1857C>T p.D619= | Silent (SNP) | VAF 14/72 reads (19%) | catalogued as rs371412265; called by muse, mutect2, varscan2
- CLMN | c.2187C>T p.F729= | Silent (SNP) | VAF 19/66 reads (29%) | catalogued as COSV54186080; called by muse, mutect2, varscan2
- CRLF1 | c.1125G>A p.K375= | Silent (SNP) | VAF 8/31 reads (26%) | catalogued as COSV62260866; called by muse, mutect2, varscan2
- CSF3 | c.519C>T p.F173= | Silent (SNP) | VAF 26/72 reads (36%) | catalogued as rs774912212, COSV56641658; ClinVar: benign; called by muse, mutect2, varscan2
- CTAG2 | c.321G>A p.R107= | Silent (SNP) | VAF 21/58 reads (36%) | catalogued as COSV55996124; called by muse, mutect2, varscan2
- CTDSPL2 | c.732G>A p.A244= | Silent (SNP) | VAF 15/55 reads (27%) | catalogued as rs551432944, COSV52947436; called by muse, varscan2
- CYP2B6 | c.1344C>A p.L448= | Silent (SNP) | VAF 11/26 reads (42%) | catalogued as rs754073421, COSV57845061; called by mutect2, varscan2
- DHRS12 | c.720G>A p.A240= (on ENST00000444610 / NM_001377930.1; = p.A191= on NM_024705.2 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 8/14 reads (57%) | catalogued as COSV54472559; called by mutect2, varscan2
- DNAJA4 | c.579C>T p.R193= (on ENST00000343789; = p.R222= on NM_018602.3) | Silent (SNP) | VAF 17/60 reads (28%) | catalogued as COSV59426520; called by muse, mutect2, varscan2
- DPYSL5 | c.963C>T p.I321= | Silent (SNP) | VAF 40/140 reads (29%) | catalogued as rs756298855, COSV56514677; called by muse, mutect2, varscan2
- EPAS1 | c.276G>A p.L92= | Silent (SNP) | VAF 22/81 reads (27%) | catalogued as COSV55388874; called by muse, mutect2, varscan2
- EPAS1 | c.441G>C p.L147= | Silent (SNP) | VAF 17/52 reads (33%) | catalogued as rs1470742039, COSV55388883; called by muse, mutect2, varscan2
- FAM47A | c.1095G>A p.A365= | Silent (SNP) | VAF 12/40 reads (30%) | catalogued as rs1375077987, COSV60498823; called by mutect2, varscan2
- FLNC | c.4920C>T p.L1640= | Silent (SNP) | VAF 33/94 reads (35%) | catalogued as rs752516424, COSV57950436; called by muse, mutect2, varscan2
- GNB1L | c.414C>T p.D138= | Silent (SNP) | VAF 11/29 reads (38%) | catalogued as rs749575241, COSV61549251; called by mutect2, varscan2
- GPR32 | c.399C>G p.V133= | Silent (SNP) | VAF 47/169 reads (28%) | catalogued as COSV54515148; called by muse, mutect2, varscan2
- GPR75 | c.1101C>T p.F367= | Silent (SNP) | VAF 14/73 reads (19%) | catalogued as rs1358916549, COSV61830687; called by muse, mutect2, varscan2
- GSAP | c.1389C>A p.L463= | Silent (SNP) | VAF 16/62 reads (26%) | catalogued as COSV57532048; called by muse, mutect2, varscan2
- HNRNPM | c.864C>T p.F288= | Silent (SNP) | VAF 28/82 reads (34%) | catalogued as rs1229573313, COSV100335367, COSV57693869; called by muse, mutect2, varscan2
- IFNAR1 | c.1008C>G p.V336= | Silent (SNP) | VAF 12/35 reads (34%) | catalogued as COSV54253548; called by muse, mutect2, varscan2
- IVL | c.141G>A p.V47= | Silent (SNP) | VAF 8/52 reads (15%) | catalogued as COSV100908105, COSV64216782; called by mutect2, varscan2
- IZUMO4 | c.348C>T p.L116= | Silent (SNP) | VAF 18/70 reads (26%) | catalogued as COSV61431275; called by muse, mutect2, varscan2
- KCNMA1 | c.3435C>T p.L1145= (on ENST00000286628 / NM_001161352.2; = p.L1087= on NM_002247.4) | Silent (SNP) | VAF 19/75 reads (25%) | catalogued as rs1449275813, COSV54271055; called by muse, mutect2, varscan2
- KEAP1 | c.948G>A p.V316= | Silent (SNP) | VAF 10/50 reads (20%) | catalogued as COSV50282948; called by muse, mutect2, varscan2
- KRT8 | c.96C>T p.R32= | Silent (SNP) | VAF 10/25 reads (40%) | catalogued as COSV53178515; called by mutect2, varscan2
- LAMA3 | c.8340C>T p.F2780= (on ENST00000313654 / NM_198129.4; = p.F1171= on NM_000227.6) | Silent (SNP) | VAF 54/134 reads (40%) | catalogued as COSV52533498; called by muse, mutect2, varscan2
- LMTK2 | c.1869C>T p.H623= | Silent (SNP) | VAF 17/67 reads (25%) | catalogued as rs141759251; called by muse, mutect2, varscan2
- MRC1 | c.3309C>G p.G1103= | Silent (SNP) | VAF 132/558 reads (24%) | called by muse, mutect2, varscan2
- MTMR8 | c.1746G>C p.L582= | Silent (SNP) | VAF 24/55 reads (44%) | catalogued as COSV66395492, COSV66395661; called by muse, mutect2, varscan2
- MTUS2 | c.474T>C p.V158= | Silent (SNP) | VAF 27/91 reads (30%) | catalogued as COSV70919194; called by muse, mutect2, varscan2
- NEUROD6 | c.171G>A p.E57= | Silent (SNP) | VAF 58/138 reads (42%) | catalogued as rs1459661331, COSV51772781; called by muse, varscan2
- NOL10 | c.2031G>A p.L677= | Silent (SNP) | VAF 99/323 reads (31%) | catalogued as COSV62041981; called by muse, mutect2, varscan2
- OGT | c.2613T>C p.S871= | Silent (SNP) | VAF 21/67 reads (31%) | catalogued as rs1172823775, COSV65482024; called by muse, mutect2, varscan2
- OR2T6 | c.276C>A p.I92= | Silent (SNP) | VAF 10/78 reads (13%) | catalogued as COSV63216852; called by mutect2, varscan2
- OR5A1 | c.588C>T p.F196= | Silent (SNP) | VAF 66/214 reads (31%) | catalogued as COSV57376501; called by muse, varscan2
- PCDH8 | c.141G>A p.G47= | Silent (SNP) | VAF 24/122 reads (20%) | catalogued as COSV58814308, COSV58814865; called by muse, mutect2, varscan2
- PCDHB10 | c.1728G>T p.V576= | Silent (SNP) | VAF 4/24 reads (17%) | called by mutect2, varscan2
- PCDHGA6 | c.1734G>C p.A578= | Silent (SNP) | VAF 51/174 reads (29%) | catalogued as COSV53953262, COSV53999620; called by muse, mutect2, varscan2
- PCLO | c.15153G>C p.V5051= | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as rs368623048; called by muse, mutect2
- PFKL | c.102C>G p.V34= | Silent (SNP) | VAF 8/17 reads (47%) | catalogued as COSV62464710, COSV62465791; called by muse, mutect2, varscan2
- PPFIA4 | c.954C>G p.L318= | Silent (SNP) | VAF 38/150 reads (25%) | catalogued as COSV55319284; called by muse, varscan2
- PREX2 | c.3387C>T p.C1129= | Silent (SNP) | VAF 34/110 reads (31%) | catalogued as COSV55789848; called by mutect2, varscan2
- PTP4A3 | c.207G>A p.P69= | Silent (SNP) | VAF 67/174 reads (39%) | catalogued as rs758014095, COSV61472485; called by muse, mutect2, varscan2
- PYGL | c.1758G>A p.T586= | Silent (SNP) | VAF 32/134 reads (24%) | catalogued as rs755485474, COSV53587613; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- RBM15 | c.216G>A p.K72= | Silent (SNP) | VAF 17/47 reads (36%) | catalogued as COSV63924004; called by muse, mutect2, varscan2
- RGL1 | c.828C>T p.I276= (on ENST00000360851 / NM_001297672.2; = p.I311= on NM_015149.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 19/60 reads (32%) | catalogued as COSV58991572; called by muse, mutect2, varscan2
- SLC1A3 | c.492G>A p.V164= | Silent (SNP) | VAF 10/34 reads (29%) | catalogued as COSV54318799; called by mutect2, varscan2
- SLC9A5 | c.1911C>T p.F637= | Silent (SNP) | VAF 10/38 reads (26%) | catalogued as rs745349628, COSV55363824; called by muse, varscan2
- ST18 | c.549G>A p.Q183= | Silent (SNP) | VAF 32/111 reads (29%) | catalogued as COSV52503544; called by muse, mutect2, varscan2
- TBC1D24 | c.63C>T p.D21= | Silent (SNP) | VAF 21/60 reads (35%) | catalogued as COSV53547816; called by muse, mutect2, varscan2
- TET2 | c.2073T>G p.T691= | Silent (SNP) | VAF 15/88 reads (17%) | catalogued as COSV54424961; called by muse, mutect2, varscan2
- TMC6 | c.2109G>A p.A703= | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as rs1397090118, COSV59810402; called by mutect2, varscan2
- TMEM132B | c.222C>T p.F74= | Silent (SNP) | VAF 49/148 reads (33%) | catalogued as rs190884960, COSV54763186; called by muse, mutect2, varscan2
- TNFAIP8L2 | c.87C>G p.L29= | Silent (SNP) | VAF 27/62 reads (44%) | catalogued as COSV64423483; called by muse, mutect2, varscan2
- TRIM65 | c.1275C>G p.L425= | Silent (SNP) | VAF 8/28 reads (29%) | called by muse, mutect2
- UBE3B | c.600C>G p.L200= | Silent (SNP) | VAF 31/118 reads (26%) | catalogued as COSV55093191, COSV55096375; called by muse, mutect2, varscan2
- WTAP | c.324G>C p.L108= | Silent (SNP) | VAF 15/70 reads (21%) | called by muse, mutect2
- ZDHHC14 | c.1059G>A p.Q353= | Silent (SNP) | VAF 13/43 reads (30%) | catalogued as COSV58195403, COSV58196842; called by muse, mutect2, varscan2
- ZER1 | c.1425C>T p.Y475= | Silent (SNP) | VAF 14/33 reads (42%) | catalogued as rs780119077, COSV52566653; called by muse, mutect2, varscan2
- ZNF175 | c.621G>A p.L207= | Silent (SNP) | VAF 20/85 reads (24%) | catalogued as COSV51797314, COSV99219513; called by muse, mutect2, varscan2
- DCHS2 | n.3927C>T | RNA (SNP) | VAF 19/37 reads (51%) | catalogued as rs1561028066, COSV61774202; called by muse, mutect2, varscan2
- DIP2C | c.157+1610G>C | Intron (SNP) | VAF 12/31 reads (39%) | catalogued as rs769199499, COSV55171591; called by muse, mutect2, varscan2
- ECM2 | c.-33C>T | 5'UTR (SNP) | VAF 17/38 reads (45%) | catalogued as COSV100755782; called by muse, mutect2, varscan2
- KIF1B | c.2115+6340G>A | Intron (SNP) | VAF 20/74 reads (27%) | catalogued as COSV55812885; called by muse, mutect2, varscan2
- MIF4GD | c.82+692G>C | Intron (SNP) | VAF 46/191 reads (24%) | catalogued as COSV55452745, COSV55454009; called by muse, mutect2, varscan2
- MIR1-1HG-AS1 | n.616A>G | RNA (SNP) | VAF 33/78 reads (42%) | called by muse, mutect2, varscan2
- RPL5 | c.528-104G>C | Intron (SNP) | VAF 38/146 reads (26%) | catalogued as COSV100240247; called by muse, mutect2, varscan2
- TTN | c.10303+1168C>A | Intron (SNP) | VAF 88/154 reads (57%) | catalogued as COSV60231280; called by mutect2, varscan2
